Somatic mutation profile of tumor specimen MMRF_2738_1_BM_CD138pos (aliquot MMRF_2738_1_BM_CD138pos_T1_KHS5U_L14888) from MMRF case MMRF_2738, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.1 years (15,739 days).
Specimen MMRF_2738_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 404bd5da-76b5-4cfe-8907-a95678f53da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2738_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2738_1_PB_WBC_C2_KHS5U_L14889; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84d7dc46-8c75-4039-9dd1-7bf20cd81944

The open-access MAF lists 66 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 15, Intron 13, Silent 7, 5'UTR 3, RNA 2, 5'Flank 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.6322C>T p.R2108C | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1246984265, CD157732, COSV57316763; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF4 | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58130560; called by muse, mutect2, varscan2
- DIPK1C | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1274621107; called by muse, mutect2
- DOCK9 | c.6008A>G p.N2003S (on ENST00000376460 / NM_001366676.2; = p.N2004S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs769582789; called by muse, mutect2, varscan2
- GAS2L1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 107/201 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1484534015; called by muse, mutect2, varscan2
- IGHV2-70 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs750213489; called by muse, varscan2
- IGHV2-70 | c.234A>T p.K78N | Missense Mutation (SNP) | VAF 86/88 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs376708751; called by muse, varscan2
- IGHV2-70 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 84/88 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs370008108; called by muse, varscan2
- IGHV2-70D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1292545219; called by muse, mutect2, varscan2
- IGKV4-1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs373106154; called by muse, mutect2, varscan2
- MUC16 | c.5440G>A p.A1814T | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); catalogued as rs1253164730; called by muse, varscan2
- POSTN | c.606G>A p.G202= | Splice Region (SNP) | VAF 16/34 reads (47%) | catalogued as rs1229286488; called by mutect2, varscan2
- SLITRK5 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104412514; called by muse, mutect2
- ACOX1 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CEP192 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.5056T>G p.Y1686D (on ENST00000297405 / NM_001363185.1; = p.Y1582D on NM_052900.3) | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CTNND2 | c.1126T>A p.S376T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); called by muse, mutect2
- DMD | c.88del p.S30Lfs*22 | Frame Shift Del (DEL) | VAF 47/69 reads (68%) | called by mutect2, pindel, varscan2
- FLRT2 | c.1907A>C p.Y636S | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- GLI2 | c.2023G>A p.G675R (on ENST00000361492 / NM_001374353.1; = p.G692R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPATCH4 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.153); called by muse, mutect2
- HNRNPA1 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2
- KLHL4 | c.887G>C p.C296S | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGM3 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.389); called by muse, mutect2
- ACCS | c.105A>G p.E35= | Silent (SNP) | VAF 82/142 reads (58%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4473T>C p.N1491= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- MAB21L2 | c.166T>C p.L56= | Silent (SNP) | VAF 86/183 reads (47%) | called by muse, mutect2, varscan2
- PCDHA5 | c.2118G>A p.V706= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV65352694; called by muse, mutect2, varscan2
- PCNT | c.870G>A p.Q290= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- SLC6A7 | c.708G>A p.V236= | Silent (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- UNC80 | c.3486C>G p.L1162= | Silent (SNP) | VAF 109/252 reads (43%) | called by muse, varscan2
- AGTR2 | c.*166C>A | 3'UTR (SNP) | VAF 27/28 reads (96%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.225+68A>C | Intron (SNP) | VAF 17/43 reads (40%) | called by mutect2, varscan2
- ASTN1 | c.*290del | 3'UTR (DEL) | VAF 24/44 reads (55%) | catalogued as rs200547682; called by mutect2, varscan2
- CCT5 | c.1499-30T>C | Intron (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- CPA4 | c.486+38T>G | Intron (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- DPPA4 | c.*1720C>T | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- EOMES | c.1380-16C>A | Intron (SNP) | VAF 77/165 reads (47%) | called by muse, mutect2, varscan2
- ERLEC1 | c.162+164C>T | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- FP565260.6 | c.*2665T>C | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as rs1323872289; called by muse, mutect2
- GIT2 | c.*2383C>T | 3'UTR (SNP) | VAF 75/205 reads (37%) | catalogued as rs553316643; called by muse, mutect2, varscan2
- GOPC | c.-93C>T | 5'UTR (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- HDAC4 | c.22+54487C>T | Intron (SNP) | VAF 76/146 reads (52%) | called by muse, mutect2, varscan2
- ITPR3 | c.*633A>G | 3'UTR (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- KAZN | c.1222+261C>T | Intron (SNP) | VAF 82/223 reads (37%) | called by muse, mutect2, varscan2
- KCNV1 | c.-144G>C | 5'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- KCTD12 | c.*3697G>A | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- KIF9 | c.1289+121T>G | Intron (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- MCTP1 | c.1212+728C>A | Intron (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- MRRFP1 | n.785G>A | RNA (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- NOL10 | c.*771G>A | 3'UTR (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- OR13C3 | chr9:104536920 C>T | 5'Flank (SNP) | VAF 65/143 reads (45%) | called by muse, mutect2, varscan2
- POU2F2 | chr19:42089164 del T | 3'Flank (DEL) | VAF 50/140 reads (36%) | called by mutect2, varscan2
- PRSS47 | n.370C>T | RNA (SNP) | VAF 7/129 reads (5%) | catalogued as rs1299328219; called by muse, mutect2
- PTK2 | c.2946+1996dup | Intron (INS) | VAF 17/44 reads (39%) | called by mutect2, varscan2
- RAB9A | c.*804A>T | 3'UTR (SNP) | VAF 29/30 reads (97%) | called by muse, mutect2, varscan2
- RNF182 | c.*689C>A | 3'UTR (SNP) | VAF 36/71 reads (51%) | catalogued as rs1002007592; called by muse, mutect2, varscan2
- SEMA3E | c.-259A>C | 5'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- SIRT2 | c.876+79T>C | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- TECRL | c.*1124A>C | 3'UTR (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- TMEM19 | c.*1906C>T | 3'UTR (SNP) | VAF 12/18 reads (67%) | catalogued as rs1046743823; called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+1529A>T | Intron (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- TNFSF10 | c.*848_*850del | 3'UTR (DEL) | VAF 20/56 reads (36%) | catalogued as rs1183308541; called by pindel, varscan2
- WDPCP | c.1748+8936G>T | Intron (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- WLS | c.*576A>G | 3'UTR (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
- ZBTB21 | c.*1991T>A | 3'UTR (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
